Somatic mutation profile of tumor specimen C3N-00834-01 (aliquot CPT0078830009) from CPTAC case C3N-00834, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 65.5 years (23,908 days).
Specimen C3N-00834-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 085907d3-a03c-4893-8904-9efa2d43299c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00834-31 (Blood Derived Normal), aliquot CPT0078870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/493afc71-633a-4006-a69e-24160f03917f

The open-access MAF lists 67 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Frame Shift Del 6, Intron 4, 5'UTR 3, RNA 3, Nonsense Mutation 2, Splice Site 2, In Frame Del 1, Splice Region 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP12 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1369315926; called by muse, mutect2
- DOT1L | c.3597-1G>T p.X1199_splice | Splice Site (SNP) | VAF 58/203 reads (29%) | catalogued as COSV101288875; called by mutect2, varscan2
- FGF10 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 112/448 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1456457163, COSV52940140; called by muse, mutect2, varscan2
- NUP210 | c.1525A>G p.I509V | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs200377773; called by muse, mutect2, varscan2
- PCDH11Y | c.563C>T p.S188F (on ENST00000400457 / NM_032973.2; = p.S177F on NM_032971.3) | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53077096, COSV53092494; called by muse, mutect2
- RABEP1 | c.1496G>C p.S499T | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs79636407; called by muse, mutect2, varscan2
- SEMA3D | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.915); catalogued as rs772215637, COSV52400436; called by muse, mutect2, varscan2
- TPTE | c.696G>T p.R232S (on ENST00000618007 / NM_199261.4; = p.R214S on NM_199259.4) | Missense Mutation (SNP) | VAF 56/778 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs756795446; called by muse, mutect2
- USH2A | c.3252G>C p.W1084C | Missense Mutation (SNP) | VAF 91/397 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); catalogued as rs200289497, COSV100230092; called by muse, mutect2, varscan2
- ZNF790 | c.1217G>A p.S406N | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.309); catalogued as rs750365504, COSV100764794; called by muse, mutect2, varscan2
- ACTR3B | c.780T>A p.N260K | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- ADAMTS20 | c.2103A>C p.L701F | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD26 | c.4097T>G p.L1366R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); called by muse, mutect2
- ASH2L | c.899G>C p.R300P | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2
- C10orf71 | c.257C>A p.P86Q | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- CD72 | c.869del p.N290Mfs*20 | Frame Shift Del (DEL) | VAF 56/231 reads (24%) | called by mutect2, pindel, varscan2
- DAB2 | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 114/474 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- FAM135B | c.1133A>G p.D378G | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- GORASP2 | c.862_868del p.Q288Sfs*7 | Frame Shift Del (DEL) | VAF 73/295 reads (25%) | called by mutect2, pindel, varscan2
- ISG20 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- KCTD15 | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KDM3A | c.2041T>A p.F681I | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.11952C>G p.Y3984* | Nonsense Mutation (SNP) | VAF 99/530 reads (19%) | called by muse, mutect2, varscan2
- LRRC7 | c.1281del p.K427Nfs*34 (on ENST00000651989 / NM_001370785.2; = p.K394Nfs*34 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- MARCHF8 | c.561del p.Q188Rfs*6 | Frame Shift Del (DEL) | VAF 58/211 reads (27%) | called by mutect2, pindel, varscan2
- MCM10 | c.1129A>G p.K377E (on ENST00000484800 / NM_182751.3; = p.K376E on NM_018518.5) | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MPEG1 | c.1826C>T p.T609I | Missense Mutation (SNP) | VAF 68/281 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYO1A | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 264/958 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYOT | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 89/410 reads (22%) | called by muse, mutect2, varscan2
- NAV3 | c.4707+1G>A p.X1569_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- NEU1 | c.801C>G p.P267= | Splice Region (SNP) | VAF 14/350 reads (4%) | called by muse, mutect2
- OR1G1 | c.723C>G p.C241W | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5L1 | c.516T>A p.N172K | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PRAMEF8 | c.1098C>A p.S366R | Missense Mutation (SNP) | VAF 95/613 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SAMD9 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- SEC16A | c.5012T>G p.I1671S | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SETD1B | c.4961T>A p.V1654E | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SUSD2 | c.1045C>A p.H349N | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- TIGD6 | c.493A>G p.K165E | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TP53RK | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TRPV4 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- UNC80 | c.645del p.W215Cfs*19 | Frame Shift Del (DEL) | VAF 53/200 reads (27%) | called by mutect2, pindel, varscan2
- VHL | c.172_198del p.R58_V66del | In Frame Del (DEL) | VAF 91/233 reads (39%) | called by mutect2, pindel, varscan2
- VWF | c.5913C>A p.S1971R | Missense Mutation (SNP) | VAF 121/422 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- WDR45 | c.534del p.K178Nfs*18 (on ENST00000376372 / NM_001029896.2; = p.K179Nfs*18 on NM_007075.3) | Frame Shift Del (DEL) | VAF 101/199 reads (51%) | called by mutect2, pindel, varscan2
- ZNF446 | c.301G>T p.V101F | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA7 | c.3111G>T p.L1037= | Silent (SNP) | VAF 52/194 reads (27%) | called by muse, mutect2, varscan2
- FAT2 | c.8331G>T p.V2777= | Silent (SNP) | VAF 9/204 reads (4%) | called by muse, mutect2
- IGBP1P2 | c.507G>T p.V169= | Silent (SNP) | VAF 33/150 reads (22%) | called by muse, mutect2, varscan2
- KCNA4 | c.828G>A p.V276= | Silent (SNP) | VAF 74/231 reads (32%) | called by muse, mutect2, varscan2
- KCTD15 | c.366G>A p.L122= | Silent (SNP) | VAF 34/137 reads (25%) | called by muse, mutect2, varscan2
- MRC1 | c.2478G>A p.A826= | Silent (SNP) | VAF 19/579 reads (3%) | catalogued as rs1331086404; called by muse, mutect2
- MTUS1 | c.3018G>T p.R1006= (on ENST00000262102 / NM_001363061.1; = p.R172= on NM_020749.4) | Silent (SNP) | VAF 184/711 reads (26%) | called by muse, mutect2, varscan2
- OR5M3 | c.705C>G p.A235= | Silent (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- PRDM15 | c.660G>A p.L220= | Silent (SNP) | VAF 107/321 reads (33%) | called by muse, mutect2, varscan2
- SNX32 | c.1146C>G p.L382= | Silent (SNP) | VAF 61/229 reads (27%) | called by muse, mutect2, varscan2
- CD59 | c.*34G>T | 3'UTR (SNP) | VAF 146/498 reads (29%) | called by muse, mutect2, varscan2
- IFNAR2 | c.541-516T>A | Intron (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- KCND3 | c.-37C>A | 5'UTR (SNP) | VAF 84/296 reads (28%) | catalogued as rs1168374991; called by muse, mutect2, varscan2
- LCN12 | c.550+269C>T | Intron (SNP) | VAF 14/102 reads (14%) | catalogued as rs1209691755; called by muse, varscan2
- NORAD | n.465G>T | RNA (SNP) | VAF 65/207 reads (31%) | called by muse, mutect2, varscan2
- OR2U1P | n.499T>C | RNA (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- RANBP3L | c.903+47G>C | Intron (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.-739C>A | 5'UTR (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- SYNE1 | c.8653-44T>A | Intron (SNP) | VAF 46/128 reads (36%) | called by muse, mutect2, varscan2
- UBBP4 | n.646C>A | RNA (SNP) | VAF 152/558 reads (27%) | called by muse, mutect2, varscan2
- ZDHHC13 | c.-48C>T | 5'UTR (SNP) | VAF 30/114 reads (26%) | called by muse, mutect2, varscan2
